Somatic mutation profile of tumor specimen 0DH29M from CCDI case PBBUAY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.0 years (1,099 days).
Specimen 0DH29M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a833f19-3a6d-4a88-995f-283ad6492f9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH27H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/910a95af-c4a2-4eda-a40b-b0eaf947c07c

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'UTR 2, Splice Site 1, RNA 1, Nonsense Mutation 1, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUL1 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 207/361 reads (57%) | catalogued as COSV57387480; called by muse, mutect2, varscan2
- GPR101 | c.1396C>A p.Q466K | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV53238598; called by muse, mutect2
- MAGEC1 | c.1882C>A p.P628T | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV53567323, COSV99596136; called by muse, mutect2, varscan2
- AKT2 | c.325A>G p.S109G | Missense Mutation (SNP) | VAF 18/558 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- BBS9 | c.2215G>T p.A739S (on ENST00000242067 / NM_001348036.1; = p.A699S on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/708 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- DOCK1 | c.1137G>A p.Q379= | Splice Region (SNP) | VAF 16/381 reads (4%) | called by muse, mutect2
- MS4A5 | c.124T>A p.L42I | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- NPAS2 | c.1140+1G>T p.X380_splice | Splice Site (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- MED12 | c.4311C>A p.T1437= | Silent (SNP) | VAF 49/302 reads (16%) | called by muse, mutect2, varscan2
- DCHS2 | n.7629G>T | RNA (SNP) | VAF 18/437 reads (4%) | called by muse, mutect2
- LRRIQ1 | c.*11C>T | 3'UTR (SNP) | VAF 49/210 reads (23%) | catalogued as rs758102429; called by muse, mutect2, varscan2
- ZNF584 | c.*5G>A | 3'UTR (SNP) | VAF 78/162 reads (48%) | catalogued as rs202096089, COSV100183193; called by muse, mutect2, varscan2
